Somatic mutation profile of tumor specimen TCGA-RW-A68B-01A (aliquot TCGA-RW-A68B-01A-11D-A35D-08) from TCGA case TCGA-RW-A68B, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.6 years (11,557 days).
Specimen TCGA-RW-A68B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbbef86b-812d-48fe-acdd-62362bb77571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A68B-10A (Blood Derived Normal), aliquot TCGA-RW-A68B-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0657e969-fe59-4c69-a02d-c42e2093c81b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABBR1 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100590260; called by muse, mutect2, varscan2
- THBS2 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.05); catalogued as rs142358231; called by muse, mutect2, varscan2
- F11R | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
